CCDI case PBBXUP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/de4c9ab0-2def-4d2a-9d9e-6b2a335b8487

Demographics
Sex at birth: female; Vital status: Dead.

Diagnoses (1)
1. Clear cell sarcoma, NOS: ICD-O-3 morphology code: 9044/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 15.2 years (5,534 days).

Biospecimens (3 samples)
- Sample 0DKPWA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKPWJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKPWT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
